Somatic mutation profile of tumor specimen MMRF_1153_4_BM_CD138pos (aliquot MMRF_1153_4_BM_CD138pos_T1_KHS5U_L14410) from MMRF case MMRF_1153, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.5 years (21,734 days).
Specimen MMRF_1153_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd626b88-b14a-41c2-a8c1-a91e5ddcc593.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1153_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1153_1_PB_Whole_C1_KHS5U_L15097; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5315b1c-f617-4697-b0a1-a14c0d92c433

The open-access MAF lists 186 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 97 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 59, Missense Mutation 56, Intron 24, Silent 22, 5'UTR 7, Nonsense Mutation 5, RNA 4, Splice Site 2, 5'Flank 2, Splice Region 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>A p.G506E (on ENST00000288602 / NM_001374244.1; = p.G466E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CUL4B | c.923dup p.L308Ffs*5 | Frame Shift Ins (INS) | VAF 9/27 reads (33%) | catalogued as rs1556216330; ClinVar: pathogenic; called by mutect2, varscan2
- AHNAK2 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs372753892; called by muse, mutect2, varscan2
- CHRM5 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs376737817; called by muse, mutect2, varscan2
- CSMD2 | c.7684C>T p.H2562Y | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs1332745877, COSV53961315; called by muse, mutect2
- FAHD2A | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764829445; called by muse, mutect2, varscan2
- FAT2 | c.10084G>A p.G3362R | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs1414501361; called by muse, mutect2, varscan2
- HEATR5A | c.3073A>G p.I1025V | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs769716098; called by muse, mutect2, varscan2
- IGHV2-70D | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1456429000; called by muse, varscan2
- KCNMA1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs202213336, COSV54259922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP2 | c.4182T>C p.D1394= | Splice Region (SNP) | VAF 18/59 reads (31%) | catalogued as rs765455128; called by muse, mutect2, varscan2
- MARS2 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs1264838638; called by muse, mutect2, varscan2
- MRC2 | c.2863G>A p.V955I | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757099340, COSV100316910; called by muse, mutect2, varscan2
- NRM | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs760639085; called by muse, mutect2, varscan2
- OR5M8 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 93/188 reads (49%) | catalogued as COSV59116574; called by muse, mutect2, varscan2
- RC3H1 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1160795981; called by muse, mutect2, varscan2
- SLC18A3 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV104400862; called by muse, mutect2, varscan2
- TDRD15 | c.1838T>C p.I613T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1424204728; called by muse, mutect2, varscan2
- TRAPPC10 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs937562044; called by muse, mutect2, varscan2
- TSR3 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs575767980, COSV50105506, COSV50105649; called by muse, mutect2, varscan2
- VCAN | c.7909G>T p.E2637* | Nonsense Mutation (SNP) | VAF 37/362 reads (10%) | catalogued as COSV54102569; called by muse, mutect2, varscan2
- ZFHX3 | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.044); catalogued as rs1397685131, COSV51723999; called by muse, mutect2, varscan2
- ZNF423 | c.88G>A p.V30M (on ENST00000563137 / NM_001379286.1; = p.V22M on NM_015069.4) | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.197); catalogued as rs778893500, COSV99284228; called by muse, mutect2, varscan2
- AC053503.6 | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- AC092032.2 | n.67+1G>A | Splice Site (SNP) | VAF 213/341 reads (62%) | called by muse, mutect2, varscan2
- ACOT7 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- AP3B1 | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCDC3 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD83 | c.105C>G p.C35W | Missense Mutation (SNP) | VAF 136/199 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CUL4B | c.1948A>G p.K650E | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- DHX15 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC11 | c.548G>C p.S183T | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EP400 | c.1249T>C p.Y417H | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAM161A | c.1633A>T p.R545* | Nonsense Mutation (SNP) | VAF 40/68 reads (59%) | called by muse, mutect2, varscan2
- FAM20C | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.12539T>C p.F4180S | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- FILIP1L | c.3165A>G p.I1055M (on ENST00000354552 / NM_182909.3; = p.I815M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HIVEP2 | c.6037A>G p.K2013E | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HPS3 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- HTR3C | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, varscan2
- KDM4B | c.2998_3000del p.S1000del | In Frame Del (DEL) | VAF 95/345 reads (28%) | called by pindel, varscan2
- KIF18A | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 14/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRTAP9-2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, varscan2
- LDLRAD3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGI4 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LSM4 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LUM | c.98C>G p.S33* | Nonsense Mutation (SNP) | VAF 136/255 reads (53%) | called by muse, mutect2, varscan2
- MAGI3 | c.2381C>T p.T794I | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARS1 | c.2147A>G p.N716S | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MNDA | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC19 | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NPHP3 | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NSD1 | c.7190G>A p.S2397N | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDHA8 | c.2111_2133del p.I704Sfs*18 | Frame Shift Del (DEL) | VAF 57/288 reads (20%) | called by mutect2, pindel
- PCLO | c.3350G>A p.G1117E | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLK2 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, varscan2
- PROM2 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRRC2C | c.5118A>C p.Q1706H (on ENST00000367742; = p.Q1704H on NM_015172.4) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RELCH | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SH3PXD2A | c.2491C>G p.P831A (on ENST00000369774 / NM_001365079.1; = p.P803A on NM_014631.2) | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SHPRH | c.439A>G p.N147D | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A21 | c.439-1G>T p.X147_splice | Splice Site (SNP) | VAF 40/120 reads (33%) | called by muse, mutect2, varscan2
- SNCAIP | c.650A>T p.H217L | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SSBP4 | c.941C>G p.P314R | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- USP29 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 81/279 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF347 | c.964T>C p.C322R | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNRF4 | c.155C>A p.S52* | Nonsense Mutation (SNP) | VAF 30/193 reads (16%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.528G>A p.G176= | Silent (SNP) | VAF 47/129 reads (36%) | called by muse, mutect2, varscan2
- ANKS3 | c.1419G>C p.G473= | Silent (SNP) | VAF 46/252 reads (18%) | called by muse, mutect2, varscan2
- CLEC18C | c.372C>A p.V124= | Silent (SNP) | VAF 42/273 reads (15%) | called by muse, mutect2, varscan2
- ERBB3 | c.882T>C p.F294= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1312311079; called by muse, mutect2, varscan2
- HTR7 | c.1210C>A p.R404= | Silent (SNP) | VAF 72/168 reads (43%) | catalogued as COSV99519229; called by muse, mutect2, varscan2
- IGHV1-69D | c.219C>A p.I73= | Silent (SNP) | VAF 84/116 reads (72%) | called by muse, mutect2, varscan2
- MADD | c.90G>A p.Q30= | Silent (SNP) | VAF 48/200 reads (24%) | catalogued as rs1476820518; called by muse, mutect2, varscan2
- NRK | c.738T>C p.T246= | Silent (SNP) | VAF 68/71 reads (96%) | called by muse, mutect2, varscan2
- PCK2 | c.795C>G p.A265= | Silent (SNP) | VAF 49/156 reads (31%) | catalogued as rs971648599; called by muse, mutect2, varscan2
- POU1F1 | c.349T>C p.L117= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as COSV60155626; called by muse, mutect2, varscan2
- PRPSAP1 | c.1107C>T p.H369= | Silent (SNP) | VAF 99/203 reads (49%) | called by muse, mutect2, varscan2
- SCN9A | c.4185T>G p.G1395= (on ENST00000303354; = p.G1384= on NM_002977.3) | Silent (SNP) | VAF 85/198 reads (43%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.558C>T p.P186= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- SYN2 | c.1071G>A p.V357= | Silent (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
- TMEM30B | c.384C>A p.R128= | Silent (SNP) | VAF 31/169 reads (18%) | called by muse, mutect2, varscan2
- TRIM68 | c.1377G>A p.L459= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- TUFT1 | c.1086G>C p.R362= | Silent (SNP) | VAF 12/113 reads (11%) | called by mutect2, varscan2
- UMPS | c.882G>A p.V294= | Silent (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- ZEB2 | c.2409A>C p.P803= | Silent (SNP) | VAF 59/130 reads (45%) | called by muse, mutect2, varscan2
- ZKSCAN7 | c.789T>C p.N263= | Silent (SNP) | VAF 53/230 reads (23%) | called by muse, mutect2, varscan2
- ZNF174 | c.393A>G p.P131= | Silent (SNP) | VAF 57/275 reads (21%) | called by muse, mutect2, varscan2
- ZNF32 | c.186G>A p.S62= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs776162310; called by muse, mutect2, varscan2
- ABHD18 | c.*1353G>A | 3'UTR (SNP) | VAF 4/8 reads (50%) | called by muse, varscan2
- AC116366.2 | c.-637-15748A>T | Intron (SNP) | VAF 35/117 reads (30%) | called by muse, mutect2, varscan2
- AKR1B10 | c.*245C>A | 3'UTR (SNP) | VAF 84/248 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*532G>A | 3'UTR (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- ASCC3 | c.241+5716A>C | Intron (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- ASF1A | c.*1424T>A | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- B3GALT1 | c.*924A>G | 3'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- BICD2 | c.2469+102G>T | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- CAND1 | c.-204C>T | 5'UTR (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- CARS1 | c.25+2370G>A | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- CBL | c.*6309A>T | 3'UTR (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- CD300A | c.*19C>T | 3'UTR (SNP) | VAF 82/187 reads (44%) | called by muse, mutect2, varscan2
- CD46 | c.-81C>T | 5'UTR (SNP) | VAF 84/258 reads (33%) | called by muse, mutect2, varscan2
- CDK6 | c.*3569C>A | 3'UTR (SNP) | VAF 34/190 reads (18%) | called by muse, mutect2, varscan2
- CHORDC1 | c.329+151T>C | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2342C>T | Intron (SNP) | VAF 21/48 reads (44%) | catalogued as rs1380994726; called by muse, mutect2, varscan2
- CREB3L2 | c.*3626C>T | 3'UTR (SNP) | VAF 75/215 reads (35%) | called by muse, mutect2, varscan2
- CSNK1A1P1 | n.165C>T | RNA (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- CXADR | c.*4241A>G | 3'UTR (SNP) | VAF 43/88 reads (49%) | called by muse, mutect2, varscan2
- CYP19A1 | c.*2228C>G | 3'UTR (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- DCC | c.*2522A>T | 3'UTR (SNP) | VAF 51/106 reads (48%) | called by muse, mutect2, varscan2
- DIPK2B | c.*1849G>T | 3'UTR (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- DIRAS2 | c.*2716A>C | 3'UTR (SNP) | VAF 24/71 reads (34%) | called by muse, mutect2, varscan2
- DNAJC27 | c.*1480G>C | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- EGLN2 | c.1168+52C>T | Intron (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- EIF2S1 | c.321+21A>T | Intron (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- EPC1 | chr10:32268594 A>G | 3'Flank (SNP) | VAF 61/115 reads (53%) | called by muse, mutect2, varscan2
- FBXO21 | c.*76C>G | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- FYCO1 | c.*1986A>C | 3'UTR (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- FYTTD1 | c.*1975A>T | 3'UTR (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2
- GABRP | c.*1171T>A | 3'UTR (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2, varscan2
- GIGYF1 | c.*924G>A | 3'UTR (SNP) | VAF 36/238 reads (15%) | called by muse, varscan2
- GIMAP5 | c.*108T>C | 3'UTR (SNP) | VAF 44/314 reads (14%) | called by muse, mutect2, varscan2
- GNAQ | c.*237dup | 3'UTR (INS) | VAF 16/55 reads (29%) | catalogued as rs1481399800; called by mutect2, varscan2
- GPR157 | c.*2912T>C | 3'UTR (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- GREB1 | c.1160-344A>T | Intron (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- GRPEL2 | c.*208T>C | 3'UTR (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- HERC4 | c.226+3919A>T | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- HOXA2 | c.392-197G>C | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- IFI35 | c.375+49G>T | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.-23T>C | 5'UTR (SNP) | VAF 39/108 reads (36%) | catalogued as rs557025310; called by muse, varscan2
- KCNK13 | c.*402C>T | 3'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- KIAA1109 | c.2794-45T>A | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- LIN28B | c.*1278T>G | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- LINC00293 | n.479-49T>A | Intron (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2, varscan2
- LINGO2 | c.*441T>A | 3'UTR (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- LYZ | c.*252C>G | 3'UTR (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2
- MAP3K21 | c.*1296T>A | 3'UTR (SNP) | VAF 37/137 reads (27%) | called by muse, mutect2, varscan2
- MBL2 | c.*630G>A | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- MFAP3L | c.298+404G>C | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- MMGT1 | c.*113A>G | 3'UTR (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- MMP1 | c.-58A>C | 5'UTR (SNP) | VAF 83/169 reads (49%) | called by muse, mutect2, varscan2
- MPND | c.1236+565C>G | Intron (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2
- MRNIP | c.538-85A>T | Intron (SNP) | VAF 39/149 reads (26%) | called by muse, mutect2, varscan2
- MRPL44 | c.*229T>C | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- MTG1 | c.573+234_573+236del | Intron (DEL) | VAF 19/40 reads (48%) | called by pindel, varscan2
- MTR | c.*537A>G | 3'UTR (SNP) | VAF 55/223 reads (25%) | called by muse, mutect2, varscan2
- MTREX | c.*731C>A | 3'UTR (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- NBPF22P | n.1520C>T | RNA (SNP) | VAF 36/191 reads (19%) | called by muse, mutect2, varscan2
- NCOA3 | c.*824T>A | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1338G>A | RNA (SNP) | VAF 38/84 reads (45%) | catalogued as rs754491024; called by muse, mutect2, varscan2
- NTRK2 | c.1585+9423C>T | Intron (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- PARVA | c.*2436T>C | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- PAX7 | c.*296G>A | 3'UTR (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- PDGFRA | c.*824T>C | 3'UTR (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- PDLIM3 | c.94-8869G>C | Intron (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- PGM3 | c.*2612T>G | 3'UTR (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- PLCB1 | c.*751C>A | 3'UTR (SNP) | VAF 16/16 reads (100%) | called by muse, mutect2, varscan2
- PPP1R3C | c.*81C>A | 3'UTR (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*2770G>T | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- PRRC2B | c.*2720del | 3'UTR (DEL) | VAF 27/210 reads (13%) | called by mutect2, pindel, varscan2
- RARRES2P7 | n.19T>C | RNA (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- RB1CC1 | c.-508C>T | 5'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- RBAK | c.*1249C>G | 3'UTR (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- RHOB | c.*604C>T | 3'UTR (SNP) | VAF 132/252 reads (52%) | called by muse, mutect2, varscan2
- RNF135 | c.*128G>A | 3'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- ROBO1 | c.*1374G>T | 3'UTR (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- RSF1 | c.*5364T>C | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- RTL6 | c.-139C>T | 5'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- SAYSD1 | c.*211_*212dup | 3'UTR (INS) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- SH3TC2 | c.1178-20A>C | Intron (SNP) | VAF 63/208 reads (30%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*1731G>A | 3'UTR (SNP) | VAF 27/46 reads (59%) | catalogued as rs1478974235; called by muse, mutect2, varscan2
- SMC1A | c.*407G>C | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- SPEG | c.2114-48C>T | Intron (SNP) | VAF 64/122 reads (52%) | catalogued as rs1393063610; called by muse, mutect2, varscan2
- SPRY2 | c.*628G>A | 3'UTR (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*4674G>A | 3'UTR (SNP) | VAF 66/149 reads (44%) | catalogued as rs565452004; called by muse, mutect2, varscan2
- ST6GAL2 | c.*4961A>G | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- SYNJ2 | c.*2215T>C | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- TAS2R20 | c.*196T>C | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- TCEAL9 | c.*195A>T | 3'UTR (SNP) | VAF 16/16 reads (100%) | catalogued as COSV101012037; called by muse, mutect2, varscan2
- TIAL1 | chr10:119596540 G>A | 5'Flank (SNP) | VAF 18/29 reads (62%) | catalogued as rs1216244576; called by muse, mutect2, varscan2
- TMEM258 | c.-20A>G | 5'UTR (SNP) | VAF 111/272 reads (41%) | catalogued as rs947740651; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975348 G>A | 5'Flank (SNP) | VAF 89/96 reads (93%) | called by muse, mutect2, varscan2
- TOX3 | c.907-52A>T | Intron (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- VAPB | c.*4218T>A | 3'UTR (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*5269G>A | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- ZNF254 | c.158-31A>T | Intron (SNP) | VAF 22/136 reads (16%) | called by muse, varscan2
